CCDI case PBBSZR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/7975dfd3-84a2-4c94-afa1-6772c0af93dc

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 13.5 years (4,927 days).

Biospecimens (3 samples)
- Sample 0DG5A5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DG5AD: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DG5AN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
